Somatic mutation profile of tumor specimen MP2PRT-PARVFZ-TMP1-A (aliquot MP2PRT-PARVFZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARVFZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,630 days).
Specimen MP2PRT-PARVFZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c164358-e0e5-481b-8b22-2d9ac212e078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVFZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVFZ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c6b78a-4963-45e3-ab7b-59ebb7470ed8

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Ins 2, Splice Site 1, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 171/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461754052; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTTNBP2 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 197/418 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50404225; called by muse, mutect2, varscan2
- DMD | c.8159G>A p.R2720H | Missense Mutation (SNP) | VAF 181/613 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs760495223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI2 | c.3512C>T p.P1171L (on ENST00000361492 / NM_001374353.1; = p.P1188L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/474 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs145212051; called by muse, mutect2, varscan2
- LAMA1 | c.8695G>A p.G2899R | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369240094, COSV67532592; called by muse, mutect2, varscan2
- LRRIQ1 | c.5017-1G>A p.X1673_splice | Splice Site (SNP) | VAF 83/171 reads (49%) | catalogued as rs1218660881; called by muse, mutect2, varscan2
- PNMA6F | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 236/796 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945789010; called by muse, mutect2, varscan2
- SHANK1 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1163284221, COSV53242350; called by muse, mutect2
- SIGLEC8 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 139/346 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs199639369, COSV58474114; called by muse, varscan2
- TTBK1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 150/495 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs774773187; called by muse, mutect2, varscan2
- ATAD5 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BTBD11 | c.2272A>G p.K758E (on ENST00000280758 / NM_001018072.2; = p.K295E on NM_001017523.2) | Missense Mutation (SNP) | VAF 132/341 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM133A | c.198T>G p.N66K | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IGHV4-59 | c.347_348insCCTAG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 22/40 reads (55%) | called by pindel, varscan2
- KIF2B | c.897C>A p.C299* | Nonsense Mutation (SNP) | VAF 171/350 reads (49%) | called by muse, mutect2, varscan2
- PAX5 | c.625_626insTGTGC p.P209Lfs*71 | Frame Shift Ins (INS) | VAF 151/397 reads (38%) | called by mutect2, pindel, varscan2
- TMEM132D | c.3139T>C p.F1047L | Missense Mutation (SNP) | VAF 179/415 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOX2 | c.1335C>A p.S445R (on ENST00000358131 / NM_001098798.2; = p.S421R on NM_032883.3) | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF695 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- FAT1 | c.1563G>A p.T521= | Silent (SNP) | VAF 155/358 reads (43%) | catalogued as rs535884977; called by muse, mutect2, varscan2
- HS6ST2 | c.234G>T p.L78= | Silent (SNP) | VAF 245/846 reads (29%) | called by muse, mutect2, varscan2
- IQANK1 | c.627G>A p.Q209= | Silent (SNP) | VAF 55/868 reads (6%) | called by muse, mutect2
- PLA2G4F | c.2253G>A p.K751= | Silent (SNP) | VAF 226/583 reads (39%) | called by muse, mutect2
- PPP1R17 | c.207G>A p.P69= | Silent (SNP) | VAF 133/292 reads (46%) | catalogued as rs374604928, COSV59610798; called by muse, mutect2, varscan2
- PYROXD1 | c.1395C>T p.T465= | Silent (SNP) | VAF 64/185 reads (35%) | catalogued as rs771041194; called by muse, mutect2, varscan2
- PXN | c.831+1816G>A | Intron (SNP) | VAF 153/319 reads (48%) | called by muse, mutect2, varscan2
- ZNF540 | c.*580G>C | 3'UTR (SNP) | VAF 135/322 reads (42%) | called by muse, mutect2, varscan2
